Surgical pathology report (de-identified scan), TCGA case TCGA-XU-AAXY, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-AAXY-01A (Primary Tumor).

[page 1 of 3]
Patient Name

MRN:
DOB: (Age:)
Gender:M

Service:
Visit #:
Location:
Facility:

Collected:
Resulted:

Ordering MD:

Surgical Pathology Consultation Report

ICD C-3

Thymoma, type B2, malignant
8584/3

SPECIMEN(S) RECEIVED

1. Thymus: Thymus Gland & Thymoma (stitch marks)

Date: Thymus
CB7.9
Qx 5/21/14

DIAGNOSIS

1. Thymectomy:
- Thymoma, WHO type B2, with extension into thymic adipose tissue.
- Maximum tumour dimension: 4.5 cm
- Tumor cells focally are present at painted margin and extend close to a putative free pleural surface.
- Closest margins: < 0.1 cm, painted mid-axis margin and short axis margins
- Residual thymus shows lymphoid follicle hyperplasia

SYNOPTIC DATA

Specimen Type:	Cervical thymectomy
Specimen Size:	Greatest dimension: 10.2 cm
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 4.5 cm
Histologic Type:	Type B thymoma, B2 (cortical)
Pathologic Staging:	Stage IIb: Macroscopic capsular invasion
Regional Lymph Nodes:	pN0: No regional lymph node metastasis
	Number of nodes examined: 1
	Number of nodes involved: 0
Distant Metastasis:	Cannot be assessed
Margins:	Margin(s) involved by tumor
	Margin(s): Focal painted margin
Invasion of Pulmonary Parenchyma:	Absent
Pleural Invasion:	Present
Vascular (Small/Large Vessel) Invasion:	Absent

Status: complete

Page: 1 of 3

[page 2 of 3]
Patient Name:

MRN:

Service:

Collected:

DOB: (Age:)

Visit #:

Resulted:

Gender:M

Location:

Facility:

Ordering MD:

ELECTRONICALLY VERIFIED BY.

GROSS DESCRIPTION

1. The specimen labeled with the patient's name and as "thymus and thymoma (stitch marks left pleural -)" consists of an irregularly shaped piece of lobulated adipose tissue with a suture on one short axis margin. The specimen has a fresh weight of 47.5 g and measures 9.0 x 10.2 x 2.6 cm. The suture is present on AP cell membranous tissue measuring 6.0 x 2.7 cm. The specimen is painted with Silver nitrate. Serial cuts of the specimen demonstrate a poorly defined tumor measuring 4.5 x 2.0 x 4.0 cm. The tumor comes to within 0.2 cm of one long axis margin, 1.5 cm of the opposite long axis margin, 0.2 cm of one mid axis margin, 1.0 cm of the opposite mid axis margin and 0.1 cm of both short axis margins (including the sutured component). The cut surface the tumor demonstrates fibrous septae with locules of congested and fleshy pink-tan material. 4 pieces of tumor and 2 pieces of thymus are submitted for

Representative sections:

- 1A tumor with one long axis margin
- 1B tumor with opposite long axis margin
- 1C tumor with one mid axis margin
- 1D tumor at opposite mid axis margin
- 1E tumor with sutured margin
- 1F tumor with margin opposite to sutured margin
- 1G uninvolved thymus

MICROSCOPIC DESCRIPTION

Sections show a tumour composed of an mixed population of small lymphoid cells and larger epithelial cells. There are small islands of purely lymphoid cells but the majority of the tumour is composed of solid sheets of the two populations. The tumour focally shows thick fibrous septae and a thin fibrous capsule that is discontinuous at the point where tumour extends into the adjacent adipose tissue. By immunohistochemistry, the epithelial tumour cells are positive for CK5/6 and HMWK. There is positive staining of the intermingled lymphoid cells with CD5, CD1a, and CD99. The background thymus shows reactive lymphoid

[page 3 of 3]
Patient Name:

MRN:

DOB: (Age:)

Gender:M

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

follicle hyperplasia. The overall morphology of the lesion is consistent with a thymoma type B2 in a background of lymphoid follicle hyperplasia, consistent with the clinical history of myasthenia gravis.

Status: complete

Page: 3 of 3

Source: NCI Genomic Data Commons file 1589b964-a231-4f9e-84ca-68f8b6fd6138 (TCGA-XU-AAXY.8FF81F34-90A2-423E-B67D-A694F941FB8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).